Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3B8, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3B8-01A (Primary Tumor).

[page 1 of 2]
Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Left pelvic lymph nodes; dissection:
- Fifteen lymph nodes, no tumor present (0/15)
- B. Right pelvic lymph nodes; dissection:
- Ten lymph nodes, no tumor present (0/10)
- C. Bladder, bilateral vas deferens; radical cystoprostatectomy:
- Urothelial carcinoma of the urinary bladder, high grade, with squamous differentiation,
- invasive into outer half of the muscularis propria.
- Margins of resection (soft tissue, prostatic urethra, right and left ureter),
- no tumor present.
- See pathologic parameters and comment.
- Prostate, seminal vesicles and vasa deferentia, no tumor present.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Urothelial carcinoma with squamous differentiation
2. Grade of tumor: High grade
3. Depth of invasion: Muscularis propria, outer half
4. Tumor distribution: Solitary, right lateral/anterior wall
- Size: 3.2 x 2.3 x 1.3 cm
5. Ureteral margins: Negative
6. Distal urethral margin: Negative
7. Soft tissue margin: Negative
8. Lymph nodes: Twenty five lymph nodes, no tumor present (0/25)
9. pTNM: pT2b, N0, Mx

Effective this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

Parts B5 and C1: Deeper levels are examined.

xxx

[], M.D

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D., Ph.D.

Electronically Signed out by [] M.D

Clinical History:

The patient is a -year-old male with malignant neoplasm of bladder undergoing radical cystectomy.

Specimens Received:

- A: Left pelvic lymph node
- B: Right pelvic lymph node
- C: Bladder, bilateral vas deferens

Reviewed/Initials	[Signature]	

Path: 145-0-3
Carcinoma, urothelial, NOS 8/20/13
Site: bladder, wall, ves, C47.9
C47.9: bladder, wall, lateral C47.9
10/21/14

[page 2 of 2]
Gross Description:

The specimens are received in three containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin is a 5.3 x 3.2 x 2.2 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 9 apparent lymph nodes ranging from 0.4-2.1 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

A1-A3: One lymph node candidate, bisected in each cassette
A4-A5: Three lymph node candidates in each cassette

B. The second container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin is a 3.5 x 2.3 x 1.3 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 10 apparent lymph nodes ranging from 0.3-3.3 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

B1, B2: One lymph node candidate, bisected in each cassette
B3, B4: Three lymph node candidates in each cassette
B5: Two lymph node candidates in each cassette

C. The third container is additionally identified as, "bladder, bilateral vas deferens". Received fresh and placed in formalin is a 38 x 21 x 12.2 cm cystoprostatectomy specimen with attached mesenteric fat. The bladder measures 8.5 x 6.1 x 5.8 cm. The right ureteral stump measures 3 cm and the left 3 cm, and both demonstrate patent lumina. The prostate gland measures 6.8 x 4.5 x 3.4 cm. The right seminal vesicle measures 7.2 x 1.5 x 1.5 cm and the right vas deferens measures 7.0 cm in length and 0.6 cm in diameter. The left seminal vesicle measures 7.5 x 1.3 x 1.3 cm and the left vas deferens measures 7.2 cm in length and 0.6 cm in diameter. The right half of the prostate is inked blue and the left half is inked black. The bladder is inked black. The prostate is opened anteriorly along the urethra and continued superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal a 1.1 x 1.0 cm area of rubbery, white, firm nodule along the right side of the prostate which is 1.0 cm from the inked surface. The bladder demonstrates a 3.2 x 2.3 cm ulceration involving right lateral wall extending to the anterior wall. Serial sectioning of the ulcer area reveals 3.2 x 2.3 x 1.3 cm rubbery, white mass invasion into the muscularis propria to a depth of 1.3 cm, extending to 0.4 cm of the inked surface. The remainder of the mucosa is tan-brown, edematous, and glistening with 1.1-1.8 cm wall thickness. The bilateral ureteral orifices are identified and probe patent. Representative sections are submitted as follows:

C1: Right ureteral margin
C2: Left ureteral margin
C3: Distal urethral margin
C4, C5: Prostatic apex
C6: Representative prostate through verumontanum
C7, C8: Representative sections of prostate nodule on the right side
C9, C10: Representative sections of normal prostate tissue on the left side
C11: Seminal vesicles and vasa deferentia
C12-C14: Multiple tumor sections, closest to the inked margin
C15: Uninvolved left wall
C16: Uninvolved posterior wall
C17: Uninvolved dome

xxx

[] MB, PhD

Source: NCI Genomic Data Commons file 2c90703a-d70f-401e-8317-693ffbb7ffc0 (TCGA-FD-A3B8.1F9298B4-73AC-4B72-946B-443278540E6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).